CPTAC case C3L-07090 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec554409-d484-4325-9ff1-319a96824023

Demographics
Sex at birth: male; Race: white; Year of birth: 1938; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 82.9 years (30,297 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 1,502 days (4.1 years); Progression or recurrence: no; Days to last follow up: 1,502 days (4.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 27.

Follow-up (3 entries)
- Days to follow up: 282 days; Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 624 days (1.7 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,149 days (3.1 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 24.8; Cigarettes per day: 15; Tobacco smoking onset year: 1967; Tobacco smoking quit year: 2000; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 33.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 480 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07090-21: Section location: Body, Antrum, Pylorus; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-07090-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 434 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-07090-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
